Gene-level copy-number profile of tumor specimen TCGA-DK-A1AC-01A from TCGA case TCGA-DK-A1AC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.0 years (26,307 days).
Specimen TCGA-DK-A1AC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.873a95ea-fc0d-4bed-b0e8-dc11c01f795c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A1AC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/351f652b-c84a-48a2-bfce-1c322a100aea

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,654; copy number 2: 9,453; copy number 3: 18,998; copy number 4: 13,112; copy number 5: 8,993; copy number 6: 3,963; copy number 7: 963; copy number 8: 464; copy number 9: 821; copy number 10: 42; copy number 11: 30; copy number 12: 14; copy number 13: 28; copy number 14: 141; copy number 15: 61; copy number 17: 13; copy number 22: 39; copy number 27: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A1AC-01A-11D-A13V-01): tumor purity 0.69, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:54,643,557–54,645,987, 1 gene: AC016583.1.
- chr8:4,633,065–4,635,654, 1 gene: AC022068.1.
- chr16:76,634,998–76,658,478, 1 gene (within-gene range 0–3): LINC02125.
- chr18:63,949,301–64,019,779, 3 genes: HMSD, AC009802.1, SERPINB8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,625 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,412,027–4,552,145, 3 genes, copy number 8: LINC01777, AL355602.1, Z98747.1.
- chr1:4,963,954–5,554,881, 8 genes, copy number 9: BX005132.1, LINC02781, LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2.
- chr1:5,564,071–5,564,143, 1 gene, copy number 9: Z97988.1.
- chr1:13,892,792–15,118,043, 6 genes, copy number 8 (within-gene range 4–8): KAZN, RNU6-1265P, AL357873.1, KAZN-AS1, TBCAP2, AL031293.1.
- chr1:147,242,654–147,842,359, 16 genes, copy number 7 (within-gene range 5–7): CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1.
- chr1:152,842,856–165,709,968, 524 genes, copy number 8–9 (broad region; genes not listed).
- chr2:27,625,638–33,399,509, 102 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr2:65,310,851–67,825,562, 34 genes, copy number 7–8 (within-gene range 5–8): SPRED2, AC012370.1, AC007389.1, AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1, AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3, MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1, LINC01828, LINC01829, AC023115.1, ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812.
- chr2:84,039,885–84,907,008, 9 genes, copy number 7 (within-gene range 5–7): ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7, TRABD2A, AC010087.1.
- chr2:91,589,494–95,991,831, 90 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:217,284,019–217,756,593, 2 genes, copy number 7 (within-gene range 4–7): DIRC3, AC010886.1.
- chr3:7,241,916–25,597,932, 283 genes, copy number 8–10 (within-gene range 6–12) (broad region; genes not listed).
- chr3:27,110,085–32,483,067, 62 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr3:32,635,222–35,256,946, 34 genes, copy number 8: RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P.
- chr4:10,284,961–10,295,579, 3 genes, copy number 10: AC006499.3, AC006499.5, AC006499.7.
- chr6:11,861,626–23,649,774, 144 genes, copy number 14–27 (broad region; genes not listed).
- chr6:39,881,804–42,217,861, 68 genes, copy number 10–15 (within-gene range 6–15) (broad region; genes not listed).
- chr6:44,513,262–45,664,349, 12 genes, copy number 7: AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1.
- chr7:67,627,831–72,447,151, 32 genes, copy number 7–11: MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66, AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2.
- chr8:33,360,839–33,513,185, 5 genes, copy number 8 (within-gene range 1–8): AC067838.1, FUT10, AC091144.2, TTI2, MAK16.
- chr8:46,028,804–46,698,688, 5 genes, copy number 8–12: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4.
- chr8:49,054,311–52,565,430, 32 genes, copy number 9–13 (within-gene range 5–13): PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1.
- chr8:60,185,412–64,462,926, 58 genes, copy number 8–10: CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1.
- chr8:120,052,180–137,645,564, 238 genes, copy number 7–9 (broad region; genes not listed).
- chr8:138,130,023–139,508,971, 7 genes, copy number 8: FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr9:26,642,697–26,805,862, 4 genes, copy number 7: AL442639.1, AL451137.2, AL451137.1, AL356133.1.
- chr10:1,957,589–8,973,468, 142 genes, copy number 9–14 (broad region; genes not listed).
- chr10:12,877,459–13,668,445, 25 genes, copy number 7 (within-gene range 4–7): AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3.
- chr10:13,675,646–13,871,175, 5 genes, copy number 7: AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5.
- chr10:50,990,888–52,298,423, 1 gene, copy number 7 (within-gene range 6–7): PRKG1.
- chr11:85,336,075–86,423,109, 24 genes, copy number 7: AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81.
- chr11:86,432,098–86,437,282, 2 genes, copy number 7: PTP4A1P6, AP001148.1.
- chr12:114,077,133–114,241,770, 5 genes, copy number 8: AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459.
- chr15:25,051,477–25,247,426, 78 genes, copy number 9 (broad region; genes not listed).
- chr16:23,463,542–26,729,126, 63 genes, copy number 12–15 (broad region; genes not listed).
- chr16:52,005,487–54,491,396, 56 genes, copy number 8–13: C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1, PHBP21, AC007346.1, AC007346.2, AC007906.2, CHD9, AC007906.1, AC079416.4, AC079416.2, AC079416.3, AC079416.1, RNA5SP427, AC007342.2, AC007342.3, AC007342.4, AC007342.5, AC007342.8, AC007342.9, RBL2, RNU6-1153P, AC007342.1, AC007342.6, AC007342.7, AKTIP, AC007497.2, RPGRIP1L, AC007497.1, FTO, AC007496.2, AC007496.3, AC007496.1, AC007347.1, AC007347.2, AC007907.1, LINC02169, IRX3, AC018553.2, AC018553.1, LINC02140, AC018553.3, AC007343.1.
- chr17:29,071,122–30,186,475, 48 genes, copy number 9: MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2, AC068025.1, RNU4-34P, TAOK1, MIR4523, RNU6-711P, RNU6-1034P, ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2, AC104982.1, EFCAB5, AC104982.3, RNY4P13, AC104996.3, AC104996.1, AC104996.2, AC104984.2, NSRP1, hsa-mir-423, MIR423, MIR3184, AC104984.3, AC104984.5.
- chr19:51,991,332–57,066,139, 381 genes, copy number 7 (broad region; genes not listed).
- chr20:4,422,186–4,525,200, 2 genes, copy number 8: AL139350.1, AL121781.1.
- chr20:10,875,333–11,029,455, 4 genes, copy number 7: AL050403.1, FAT1P1, LINC02871, AL158042.1.

Autosomal genes at a single copy (total copy number 1): 1,171. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
